Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7645, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7645-01A (Primary Tumor).

[page 1 of 3]
ORIGINAL REPORT

SPECIMEN:

- A. Periportal lymph node.
- B. Gallbladder.
- C. Bile duct margin.
- D. Pancreas margin.
- E. Superior mesenteric lymph nodes (fresh)
- F. Pancreas (Whipple's specimen)
- G. Omentum.

CLINICAL HISTORY:

Pancreatic cancer.

DIAGNOSIS:

- A: "PERIPORTAL" LYMPH NODE;
- REACTIVE LYMPH NODE WITH NO EVIDENCE OF MALIGNANCY.
- B: GALLBLADDER (CHOLECYSTECTOMY);
- NO EVIDENCE OF MALIGNANCY.
- C: BILE DUCT MARGIN;
- NO EVIDENCE OF MALIGNANCY OR DYSPLASIA.
- D: PANCREAS MARGIN;
- CHRONIC PANCREATITIS WITH EXTENSIVE FIBROSIS, NO EVIDENCE OF MALIGNANCY.
- E: "SUPERIOR MESENTERIC" LYMPH NODE;
- REACTIVE LYMPH NODE WITH NO EVIDENCE OF MALIGNANCY.
- F: PANCREAS (WHIPPLE'S SPECIMEN);
- PANCREATIC ADENOCARCINOMA (PLEASE SEE PROGNOSTIC INDICES BELOW).
- G: OMENTUM (OMENTECTOMY);
- NO EVIDENCE OF MALIGNANCY.

PROGNOSTIC INDICES

TUMOR SITE: Head of pancreas/common bile duct

TUMOR TYPE: Adenocarcinoma

GRADE: Well-Differentiated

MAXIMUM SIZE: 4.5 CM

INVOLVEMENT OF ADJACENT STRUCTURES: Small bowel wall, Ampulla of Vater, peripancreatic adipose tissue.

FINAL

[page 2 of 3]
Inquiry Numbers:

Division Head:

DIAGNOSIS:

LYMPH VASCULAR INVASION:	Present	}
PERINEURAL INVASION:	Present	
SURGICAL RESECTION MARGINS:		
STOMACH:	Negative	
DUODENUM:	Negative	
PANCREATIC:	Negative	
BILE DUCT:	Negative	
LYMPH NODES: # POSITIVE:	5	# EXAMINED: 17
OTHER FINDINGS:	Severe chronic pancreatitis, patchy dysplasia along pancreatic/common bile duct.	

GROSS DESCRIPTION:

The specimen comes in in seven separate containers labelled with the patient's name.

A. The specimen is labelled "periportal lymph node". The specimen consists of one piece of large tan firm lymphoid tissue which measures .8 cm in largest dimension. The specimen is submitted in toto in A.

B. The specimen is labelled "gallbladder", consists of a gallbladder which measures 12.0 x 5.0 cm. The gallbladder contains about 15 ml of dark green bile with no stones identified. The serosal surface of the gallbladder is smooth. The gallbladder wall is slightly thickened and the mucosa is grossly unremarkable. Representative sections of the gallbladder neck and the body is submitted in B.

C. The specimen consists of one piece of tissue 3.0 cm in maximum dimension. Submitted in toto for QG. [REDACTED]

The specimen is labelled "duct margin" and submitted for frozen section. [REDACTED]

FINAL

[page 3 of 3]
Inquiry Numbers:

Division Head:

GROSS DESCRIPTION:

D. The specimen consists of one piece of tissue, 2.5 x 2.0 x 0.5 cm. Submitted in toto for QS. [REDACTED]

The specimen is submitted in toto for frozen section. [REDACTED]

E. The specimen is labelled "superior mesenteric lymph node" and consists of one piece of lymphoid tissue which measures 2.0 cm in largest dimension. The specimen is submitted in toto in X.

F. The specimen is labeled "pancreas, (Whipple's specimen)". The specimen is composed of the head of the pancreas, which measures 6.0 x 5.0 x 2.5 cm with attached lower segment of stomach, which measures 7.0 x 5.0 cm and duodenal tissue which measures 24.5 cm in length and 4.5 cm in circumference. A tumor mass measures 4.5 x 2.0 x 2.5 cm is identified in the pancreas surrounding the common bile duct. The tumor mass is poorly circumscribed and yellow/white in color. There are areas of cystic formation and no area of hemorrhage or necrosis in the tumor. The common bile duct is patent and the tumor has been previously cut along the common bile duct. The tumor is in contact with the ampulla grossly, and is about 3.7 cm away from the bile duct resection margin. The stomach and the upper segment of the duodenal mucosa is grossly unremarkable. The mucosal surface of the lower 8.5 cm of the duodenum is hemorrhagic in color.

Representative sections of the specimen are submitted as follows:

- F1 - is the enface pancreatic resection margin.
- F2, F3 - tissue from uncinate pancreas.
- F4 - bile duct resection margin.
- F5 - stomach resection margin.
- F6 - duodenal resection margin.
- F7 to F9 - serial section of the ampulla region.
- F10 to F19 - serial section of the tumor along the common bile duct (from close to ampulla to far from ampulla.
- F20 - tumor and small bowel.
- F21 and F22 - tumor extending close to the serosal surface of pancreas.
- F23 - random sections of the duodenum.
- F24 and F25 - lymphoid tissue.
- F26 - three lymph nodes.
- F27 - one lymph node.

FINAL

Source: NCI Genomic Data Commons file 693973a6-0342-48c4-9a87-259960b2341c (TCGA-IB-7645.8A7E8A98-1835-4CC1-8C30-AA6BBBB1DCBC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).